Somatic mutation profile of tumor specimen C3N-00194-04 (aliquot CPT0014180016) from CPTAC case C3N-00194, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.7 years (18,885 days).
Specimen C3N-00194-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39d22334-b9d2-45b0-a929-fb9b9487ce17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00194-31 (Blood Derived Normal), aliquot CPT0015040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92777734-9c98-4161-9e48-8034051b8bc5

The open-access MAF lists 82 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 15, Nonsense Mutation 5, Intron 4, Frame Shift Del 4, 3'UTR 2, Splice Site 2, RNA 2, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 125/544 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143985153, CM004284, COSV56546846, COSV56547129; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30BL | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as rs1248387408; called by muse, mutect2, varscan2
- BTRC | c.496G>T p.G166W (on ENST00000370187 / NM_033637.4; = p.G130W on NM_003939.5) | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99058528; called by muse, mutect2
- DCTN1 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 51/656 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1406215076, COSV62621314; called by muse, mutect2
- DISP3 | c.3058G>A p.V1020I | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770679216, COSV53820529; called by muse, mutect2
- DTWD1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1349922146, COSV52071861, COSV52072012; called by muse, mutect2, varscan2
- DYSF | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs139258703, CM055157; called by muse, mutect2, varscan2
- ERBB2 | c.2827C>A p.Q943K | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54073307; called by muse, mutect2, varscan2
- FGB | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1231024274; called by muse, mutect2
- KIAA0319L | c.392T>A p.L131* | Nonsense Mutation (SNP) | VAF 31/188 reads (16%) | catalogued as rs766020293; called by muse, mutect2, varscan2
- NDUFA7 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs781196681; called by muse, mutect2, varscan2
- NSD1 | c.6703C>T p.H2235Y | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as rs1289043115; called by muse, mutect2, varscan2
- PDE1C | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs762050534, COSV58520743; called by muse, mutect2, varscan2
- PFKL | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57394605; called by muse, mutect2
- PRX | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99398219; called by muse, mutect2
- SI | c.4062+1G>T p.X1354_splice | Splice Site (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100017400; called by muse, mutect2
- SLC17A9 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374675240; called by muse, mutect2, varscan2
- TUBB8 | c.165C>T p.S55= | Splice Region (SNP) | VAF 21/274 reads (8%) | catalogued as rs1554738859, COSV59118011; called by muse, mutect2
- AC068580.4 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRD1 | c.1878G>C p.E626D | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- ATP9A | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf100 | c.327del p.A110Pfs*56 | Frame Shift Del (DEL) | VAF 45/280 reads (16%) | called by mutect2, pindel, varscan2
- CDH23 | c.4400T>A p.F1467Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP95 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- CHGB | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.09); called by muse, mutect2
- DEFB134 | c.59-9_59-1del p.X20_splice | Splice Site (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel
- DNMT3L | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- EMILIN1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- F2R | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- FSCN1 | c.1216G>C p.A406P | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- GLYATL3 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HEATR5A | c.4511T>C p.I1504T | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- HERC5 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- HS3ST4 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- MED30 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MORC3 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.178); called by muse, mutect2
- NEO1 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.214); called by muse, mutect2
- NINL | c.2200del p.R734Gfs*8 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- NOP56 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCDH15 | c.5574del p.K1859Sfs*4 | Frame Shift Del (DEL) | VAF 50/437 reads (11%) | called by mutect2, pindel, varscan2
- PDE6C | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHA6 | c.1498A>G p.M500V | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); called by muse, mutect2
- PNPLA1 | c.658T>C p.F220L (on ENST00000394571 / NM_001374623.1; = p.F125L on NM_173676.2) | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PNPLA5 | c.878A>C p.N293T | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- PROM1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RANBP10 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2
- RELN | c.2031C>A p.F677L | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.914); called by muse, mutect2
- ROCK1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SGPP1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- SLC5A3 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPC24 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SUPV3L1 | c.2177C>G p.P726R | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SWSAP1 | c.493del p.Q165Sfs*33 (on ENST00000312423; = p.Q186Sfs*33 on NM_175871.4) | Frame Shift Del (DEL) | VAF 102/548 reads (19%) | called by mutect2, pindel*, varscan2
- TSC22D1 | c.3074A>C p.N1025T (on ENST00000458659 / NM_183422.4; = p.N96T on NM_006022.4) | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TTN | c.34744C>G p.P11582A (on ENST00000591111; = p.P10655A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/243 reads (8%) | PolyPhen benign (0.003); called by muse, mutect2
- YLPM1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- ZBTB46 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AMBP | c.585A>G p.P195= | Silent (SNP) | VAF 23/260 reads (9%) | catalogued as COSV54325764; called by muse, mutect2
- ARFGEF3 | c.4228T>C p.L1410= | Silent (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- FMO5 | c.750A>G p.Q250= | Silent (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- GANAB | c.1326C>T p.D442= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- HS3ST4 | c.198G>A p.Q66= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- IGHV3-53 | c.15G>A p.L5= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- INTS1 | c.2628C>T p.L876= | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as rs765127527, COSV67176825; called by muse, mutect2
- KLF9 | c.129G>A p.V43= | Silent (SNP) | VAF 14/197 reads (7%) | catalogued as COSV101009614; called by muse, mutect2
- LRRC49 | c.1458A>G p.A486= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs956094812; called by muse, mutect2, varscan2
- MYBPC1 | c.1716G>C p.R572= (on ENST00000550270 / NM_206820.2; = p.R597= on NM_002465.4) | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- NR2F1 | c.759C>T p.R253= | Silent (SNP) | VAF 20/372 reads (5%) | catalogued as COSV59070007; called by muse, mutect2
- PCDHGA5 | c.1905A>G p.R635= | Silent (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- RUNDC1 | c.36G>A p.T12= | Silent (SNP) | VAF 66/492 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10581T>A p.I3527= (on ENST00000591111; = p.I3481= on NM_003319.4) | Silent (SNP) | VAF 21/239 reads (9%) | called by muse, mutect2
- VPS39 | c.2124T>A p.I708= (on ENST00000348544 / NM_001301138.2; = p.I697= on NM_015289.5) | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- AP4B1 | c.*16del | 3'UTR (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- CABP7 | c.-50_-49del | 5'UTR (DEL) | VAF 17/138 reads (12%) | called by mutect2, pindel
- CAT | c.*9C>T | 3'UTR (SNP) | VAF 67/449 reads (15%) | called by muse, mutect2, varscan2
- CTNNB1 | c.1185+28G>A | Intron (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.386+16169G>T | Intron (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- LINC01948 | n.390G>A | RNA (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- OR4C4P | n.490G>T | RNA (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- PRSS27 | c.237-41C>T | Intron (SNP) | VAF 22/248 reads (9%) | catalogued as rs200616593; called by muse, mutect2
- PXN | c.832-1366C>T | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- Y_RNA | chr12:54102373 C>T | 5'Flank (SNP) | VAF 28/335 reads (8%) | called by muse, mutect2
